Somatic mutation profile of tumor specimen TCGA-N6-A4VC-01A (aliquot TCGA-N6-A4VC-01A-11D-A28R-08) from TCGA case TCGA-N6-A4VC, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage III; Age at diagnosis: 83.9 years (30,643 days).
Specimen TCGA-N6-A4VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac0e7f20-fded-4ddc-9899-d9e811726543.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N6-A4VC-11A (Solid Tissue Normal), aliquot TCGA-N6-A4VC-11A-11D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d02c2184-e9dc-4719-95cf-69076b2275a1

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Nonsense Mutation 5, Frame Shift Del 3, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 82/93 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACTN2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148189507, COSV63975769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.6319G>A p.A2107T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs139080127; called by muse, mutect2, varscan2
- DSCAM | c.2275G>T p.E759* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV68025190; called by muse, mutect2, varscan2
- FBXW7 | c.1499A>G p.H500R (on ENST00000281708 / NM_001349798.2; = p.H420R on NM_018315.5) | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55925905; called by muse, mutect2, varscan2
- FOXA2 | c.197C>A p.S66* (on ENST00000377115 / NM_153675.3; = p.S72* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 66/113 reads (58%) | catalogued as COSV101008551; called by muse, mutect2, varscan2
- GABRB2 | c.1357C>T p.R453* (on ENST00000274547; = p.R415* on NM_000813.3) | Nonsense Mutation (SNP) | VAF 50/99 reads (51%) | catalogued as rs1461566727, COSV99197652; called by muse, mutect2, varscan2
- KLHDC7B | c.1528C>T p.R510C (on ENST00000395676; = p.R1151C on NM_138433.5) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750273973, COSV67464640; called by muse, mutect2, varscan2
- MID1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1169366982, COSV58198773; called by muse, mutect2, varscan2
- MSH6 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.16); catalogued as rs587779934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PACS1 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762496747, COSV57696688; called by muse, mutect2, varscan2
- PKN2 | c.2236A>G p.M746V | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV65142146; called by muse, mutect2, varscan2
- SETD1A | c.2114G>A p.G705D | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99352440; called by muse, mutect2, varscan2
- SPOP | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV61654573; called by muse, mutect2, varscan2
- VN1R2 | c.786T>A p.Y262* | Nonsense Mutation (SNP) | VAF 83/107 reads (78%) | catalogued as rs1274214885, COSV59039657; called by muse, mutect2, varscan2
- ZAR1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1458104571, COSV56719477; called by muse, mutect2, varscan2
- ABCB7 | c.207G>T p.L69F (on ENST00000373394 / NM_001271696.3; = p.L70F on NM_004299.6) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- ADGRL2 | c.1421C>G p.S474C | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- AMER1 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CEP68 | c.1401del p.E467Dfs*23 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | called by mutect2, pindel, varscan2
- EPS15 | c.2411A>G p.D804G | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FCN1 | c.217+2T>C p.X73_splice | Splice Site (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- IGSF10 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IRX6 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- LDHD | c.151C>G p.R51G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- LRIF1 | c.2127T>A p.N709K | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MINDY4 | c.46del p.E16Sfs*8 | Frame Shift Del (DEL) | VAF 8/9 reads (89%) | called by mutect2, varscan2
- NFAT5 | c.1336_1382del p.E446Rfs*14 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel
- NHLRC2 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NIBAN1 | c.1772G>C p.G591A | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCHD4 | c.1211T>A p.I404N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SALL3 | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC38A5 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SLCO1B3 | c.1144A>C p.T382P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- SPOP | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 147/176 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- THSD7A | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- ZFC3H1 | c.1999A>T p.R667* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- ZNF662 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- ASPHD1 | c.1071C>T p.P357= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs781273936; called by muse, mutect2, varscan2
- DOCK6 | c.3792C>T p.T1264= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs745691615, COSV53915934; ClinVar: likely benign; called by muse, mutect2, varscan2
- DSP | c.8094C>T p.F2698= | Silent (SNP) | VAF 70/322 reads (22%) | catalogued as rs1201885200, COSV100672874; called by muse, mutect2, varscan2
- EXOSC3 | c.42C>T p.G14= | Silent (SNP) | VAF 35/38 reads (92%) | called by muse, mutect2, varscan2
- FAM47C | c.1998C>A p.L666= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV63729354; called by muse, mutect2, varscan2
- FANCM | c.1138A>C p.R380= | Silent (SNP) | VAF 49/60 reads (82%) | called by muse, mutect2, varscan2
- HCCS | c.747A>G p.L249= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- LPA | c.4851C>T p.Y1617= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as rs764894583; called by muse, mutect2, varscan2
- NFKBIL1 | c.918G>A p.G306= | Silent (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- OR2T3 | c.801G>A p.P267= | Silent (SNP) | VAF 79/400 reads (20%) | catalogued as rs370677701; called by muse, mutect2
- TAF1 | c.2346T>C p.H782= (on ENST00000373790 / NM_138923.4; = p.H803= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- TMEM236 | c.801C>T p.Y267= | Silent (SNP) | VAF 181/407 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.60036G>T p.A20012= (on ENST00000591111; = p.A12588= on NM_003319.4) | Silent (SNP) | VAF 72/323 reads (22%) | catalogued as COSV60164190; called by muse, mutect2, varscan2
- WNT9B | c.951G>A p.G317= | Silent (SNP) | VAF 85/97 reads (88%) | called by muse, mutect2, varscan2
- PAQR6 | c.*59G>A | 3'UTR (SNP) | VAF 93/233 reads (40%) | called by muse, mutect2, varscan2
- ZNF99 | c.*226C>T | 3'UTR (SNP) | VAF 38/79 reads (48%) | catalogued as COSV68055310; called by muse, mutect2, varscan2
